Somatic mutation profile of tumor specimen TCGA-95-7948-01A (aliquot TCGA-95-7948-01A-11D-2184-08) from TCGA case TCGA-95-7948, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 42.1 years (15,363 days).
Specimen TCGA-95-7948-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98fb39e9-baa9-45eb-9024-8066f648fa65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7948-10A (Blood Derived Normal), aliquot TCGA-95-7948-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6621a8f6-e61c-4c68-b042-eac761721381

The open-access MAF lists 149 somatic variants for this specimen: 119 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 23, Nonsense Mutation 10, Frame Shift Del 3, Intron 3, 5'Flank 2, Splice Region 1, 3'Flank 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 27/193 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV52517787, COSV52518375; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AAK1 | c.2448C>A p.S816R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1282160106; called by muse, mutect2
- AC023055.1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV60243836; called by muse, mutect2, varscan2
- AKAP17A | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV58311024; called by muse, mutect2, varscan2
- ALG8 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55201441; called by muse, mutect2, varscan2
- ALOX15B | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1460490422, COSV66479809; called by muse, mutect2, varscan2
- ALPK2 | c.2174G>C p.R725T | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV64494825; called by muse, mutect2, varscan2
- APLP2 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53842387; called by muse, mutect2, varscan2
- ASB12 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62857291; called by muse, mutect2
- ASH1L | c.5902T>G p.L1968V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.025); catalogued as COSV64210819; called by muse, mutect2, varscan2
- BMP2K | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV55010847; called by muse, varscan2
- C2CD3 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs759687227, COSV58095604, COSV58096182; called by muse, mutect2, varscan2
- CACNA1A | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs779989955, COSV64204868; called by muse, mutect2, varscan2
- CAPN1 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54196898, COSV54200156; called by muse, mutect2, varscan2
- CASP1 | c.1168G>A p.E390K (on ENST00000436863 / NM_033292.4; = p.E369K on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52830267; called by muse, mutect2, varscan2
- CCDC87 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs762394264, COSV59579483, COSV59579788; called by muse, mutect2, varscan2
- CCNP | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV55688165; called by muse, mutect2, varscan2
- CDSN | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV52539017; called by muse, mutect2, varscan2
- CNTD1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV100162097; called by muse, mutect2, varscan2
- COL13A1 | c.1213G>A p.D405N (on ENST00000398978 / NM_001130103.2; = p.D348N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.356); catalogued as rs117194484, COSV100637461; called by muse, mutect2, varscan2
- COL5A3 | c.3337C>T p.P1113S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.2); catalogued as rs752175069, COSV53415178; called by muse, mutect2
- CSNK1E | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV63291624; called by muse, mutect2
- CSNK1G1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV57311968; called by muse, mutect2, varscan2
- CYP11B1 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52828941; called by muse, mutect2, varscan2
- DENND3 | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52804488; called by muse, mutect2, varscan2
- DGKA | c.1812C>A p.S604R | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59387397; called by muse, mutect2, varscan2
- DHPS | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52952632; called by muse, mutect2, varscan2
- DPYSL3 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV58328367, COSV58328842; called by muse, mutect2, varscan2
- DPYSL4 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs758420742, COSV53843189; called by muse, mutect2
- DSG3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV57128022; called by muse, mutect2, varscan2
- EBF3 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62478170; called by muse, mutect2, varscan2
- EIF3B | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV62804095; called by muse, mutect2, varscan2
- ERICH5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 36/210 reads (17%) | catalogued as rs773430461, COSV59316518; called by muse, mutect2, varscan2
- FAT4 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.204); catalogued as COSV67893675; called by muse, mutect2, varscan2
- FIG4 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV57789362; called by muse, mutect2, varscan2
- FLG | c.4801G>C p.E1601Q | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as rs774105195, COSV64244936; called by muse, mutect2, varscan2
- FOLH1 | c.2073C>G p.I691M | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs963654912, COSV57052818; called by muse, mutect2, varscan2
- FSD2 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100575298, COSV58011355; called by muse, mutect2, varscan2
- GALK1 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as CM001700, COSV52329612; called by muse, mutect2, varscan2
- GALNT1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV52453748; called by muse, mutect2, varscan2
- GCNA | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV65467624; called by muse, mutect2, varscan2
- GLCCI1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56203535; called by muse, mutect2, varscan2
- GNB1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66101175; called by muse, mutect2
- GNB5 | c.624G>A p.M208I (on ENST00000261837 / NM_016194.4; = p.M166I on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.944); catalogued as COSV55900266; called by muse, mutect2, varscan2
- H2AC13 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV100704385, COSV62440550; called by muse, mutect2
- H2AC14 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV60797961; called by muse, mutect2, varscan2
- H3-5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as rs866971809, COSV61186810; called by muse, mutect2
- HAPLN4 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.115); catalogued as COSV52270517; called by muse, mutect2, varscan2
- HERC1 | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101496543; called by muse, mutect2, varscan2
- HIF1AN | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1239964175, COSV54501281, COSV54502352; called by muse, mutect2, varscan2
- IER3IP1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as COSV56506558; called by muse, mutect2, varscan2
- IGSF5 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV66030231; called by muse, mutect2, varscan2
- IL22RA1 | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV54629497; called by muse, mutect2, varscan2
- ITGAM | c.1692C>G p.I564M (on ENST00000648685 / NM_001145808.2; = p.I563M on NM_000632.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV54939703; called by muse, mutect2, varscan2
- KIAA1109 | c.8136C>G p.F2712L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); catalogued as COSV52683249; called by muse, mutect2, varscan2
- KIF3C | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs753614267, COSV53100745; called by muse, mutect2, varscan2
- LAMB2 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV59731869, COSV59737816; called by muse, mutect2, varscan2
- LIN7B | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55522027; called by muse, mutect2, varscan2
- LMAN1L | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs551657514, COSV59002748; called by muse, mutect2, varscan2
- LRP5 | c.2777G>A p.C926Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53719636; called by muse, mutect2, varscan2
- MAGEE2 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100973069; called by muse, mutect2
- MASTL | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60911713; called by muse, mutect2, varscan2
- MINDY4 | c.1014G>C p.M338I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54676321; called by muse, mutect2, varscan2
- MMUT | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV51277321; called by muse, mutect2
- MYRIP | c.1881G>C p.Q627H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100218457, COSV56875606; called by muse, mutect2, varscan2
- N4BP2 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV54704546; called by muse, mutect2, varscan2
- N4BP2 | c.2817G>C p.K939N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV54704558; called by muse, mutect2, varscan2
- NECTIN3 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60552498, COSV60553935; called by muse, mutect2, varscan2
- NPHP1 | c.1387C>G p.P463A (on ENST00000393272 / NM_207181.4; = p.P464A on NM_000272.5) | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV57210115; called by muse, mutect2, varscan2
- NPRL2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV51603093; called by muse, mutect2, varscan2
- NRXN1 | c.2613C>A p.S871R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV58472888; called by muse, mutect2, varscan2
- OR8H3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100538678, COSV57908287, COSV57908569; called by muse, mutect2, varscan2
- PARD3 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1186195419, COSV60755276; called by muse, mutect2, varscan2
- PCDH10 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.232); catalogued as COSV52099270; called by muse, mutect2, varscan2
- PCDHA7 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV65345884; called by muse, mutect2, varscan2
- PGBD1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV52554786; called by muse, mutect2, varscan2
- PHLDA2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV56540958; called by muse, mutect2, varscan2
- PIWIL1 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV55344391; called by muse, mutect2, varscan2
- PKD1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as COSV51920778, COSV99237357; called by muse, mutect2, varscan2
- PLCB1 | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV62059824; called by muse, mutect2, varscan2
- PLEKHM2 | c.130del p.R44Vfs*93 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV65395100; called by mutect2, varscan2
- PLEKHO1 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV50310805; called by muse, mutect2, varscan2
- PLEKHS1 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63056103; called by muse, mutect2, varscan2
- PPP1R3A | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as COSV52887278, COSV52887524, COSV52894554; called by muse, mutect2, varscan2
- PPP1R9B | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs753589837, COSV57541903; called by muse, mutect2, varscan2
- PRKDC | c.9583G>A p.E3195K | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV58058436; called by muse, mutect2, varscan2
- PUM2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.306); catalogued as COSV57583553; called by muse, mutect2, varscan2
- RBMXL1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV53103538; called by muse, varscan2
- RDH8 | c.307G>C p.E103Q (on ENST00000651512; = p.E83Q on NM_015725.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV50676228; called by muse, mutect2, varscan2
- REM1 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV52429176; called by muse, mutect2, varscan2
- ROCK2 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55081961; called by muse, mutect2, varscan2
- RTN2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs774055201, COSV55595182; called by muse, mutect2, varscan2
- SAYSD1 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs750084982, COSV57723342; called by muse, mutect2, varscan2
- SERINC5 | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV101549042, COSV72216483; called by muse, mutect2
- SOS1 | c.2814G>C p.L938F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV67676504; called by muse, mutect2, varscan2
- SRR | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205780730, COSV56786061; called by muse, mutect2, varscan2
- TAF5 | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58916054; called by muse, mutect2, varscan2
- TAF7L | c.763T>A p.Y255N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV61257611; called by muse, mutect2
- TBC1D22A | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761224095, COSV61442477; called by muse, mutect2, varscan2
- TCF25 | c.1023G>C p.R341S | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54530762; called by muse, mutect2, varscan2
- TEAD3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as rs369194515, COSV58817595; called by muse, mutect2, varscan2
- TLR7 | c.3104C>G p.T1035R | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV66124851; called by muse, mutect2
- TMC4 | c.2101C>T p.R701C (on ENST00000617472 / NM_001145303.3; = p.R695C on NM_144686.4) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55365854; called by muse, mutect2, varscan2
- TMEM87A | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67747522; called by muse, mutect2, varscan2
- TMEM94 | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV58598148; called by muse, mutect2, varscan2
- TNXB | c.9103G>A p.E3035K (on ENST00000647633; = p.E2788K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.388); catalogued as rs1562802791, COSV64483460; called by muse, mutect2, varscan2
- UBR1 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as COSV51933296; called by muse, mutect2, varscan2
- ZFC3H1 | c.4426C>T p.Q1476* | Nonsense Mutation (SNP) | VAF 15/199 reads (8%) | catalogued as COSV66434395; called by muse, mutect2
- ZMYM3 | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58739383, COSV58740729; called by muse, mutect2, varscan2
- ZNF544 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as COSV54137037; called by muse, mutect2, varscan2
- ZNF561 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57178281; called by muse, mutect2, varscan2
- ZNF583 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV52401006, COSV52403161; called by muse, mutect2, varscan2
- ZNF638 | c.3862C>G p.P1288A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52486505, COSV52491814; called by muse, mutect2, varscan2
- ZNF804A | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56454928; called by muse, mutect2, varscan2
- ANKRD50 | c.*2del | Splice Region (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- BAP1 | c.1661del p.G554Vfs*17 | Frame Shift Del (DEL) | VAF 61/109 reads (56%) | called by mutect2, pindel, varscan2
- CNDP2 | c.9_14del p.L4_T5del | In Frame Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- WWP2 | c.274del p.R92Efs*5 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- ABCA12 | c.1827C>T p.I609= (on ENST00000272895 / NM_173076.3; = p.I291= on NM_015657.3) | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1167221734, COSV55967692; called by muse, mutect2, varscan2
- ACSBG2 | c.1131C>G p.L377= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV53126351, COSV53126704; called by muse, mutect2, varscan2
- BPTF | c.1419G>A p.L473= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV58841918; called by muse, mutect2, varscan2
- CNTD1 | c.549G>C p.L183= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100162096; called by muse, mutect2, varscan2
- CRYBG2 | c.619C>T p.L207= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- DDX46 | c.2334C>T p.F778= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV62800152; called by muse, mutect2, varscan2
- H2BC4 | c.36G>A p.K12= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs1457328255, COSV58417015; called by muse, mutect2, varscan2
- KIF2B | c.1977G>C p.L659= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1048430372, COSV52133274; called by muse, mutect2, varscan2
- MUC5AC | c.15336C>T p.V5112= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs756797156, COSV100611430; called by muse, mutect2, varscan2
- OR51L1 | c.96C>G p.L32= | Silent (SNP) | VAF 13/236 reads (6%) | catalogued as COSV58625276; called by muse, mutect2
- OR9G4 | c.396T>C p.Y132= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV57249232; called by muse, mutect2
- PLXNA4 | c.5472C>T p.I1824= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as COSV58144240; called by muse, mutect2, varscan2
- PTCH1 | c.595T>C p.L199= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV59484771; called by muse, mutect2, varscan2
- RNASE1 | c.387G>A p.P129= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs746951001, COSV61754127; called by muse, mutect2, varscan2
- STRN4 | c.1164C>T p.I388= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs777955776, COSV99623620; called by muse, mutect2, varscan2
- TCL1A | c.344G>A p.*115= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV68085924; called by muse, mutect2, varscan2
- TLR2 | c.1554A>G p.Q518= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as rs376583514, COSV52607345; called by muse, mutect2, varscan2
- TOGARAM1 | c.51C>T p.L17= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV61888849; called by muse, mutect2, varscan2
- TTC21B | c.2349G>A p.L783= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV54632763; called by muse, mutect2, varscan2
- UBOX5 | c.531C>A p.I177= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV53907559; called by muse, mutect2, varscan2
- UGT3A2 | c.561C>T p.F187= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV56932144; called by muse, mutect2, varscan2
- XRCC1 | c.1206C>G p.L402= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53449464, COSV99486452; called by muse, mutect2, varscan2
- ZNF607 | c.207G>A p.V69= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV62205885; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505574 C>G | 5'Flank (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+2803C>T | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100734234; called by muse, mutect2, varscan2
- LDB3 | c.690-4791G>A | Intron (SNP) | VAF 87/312 reads (28%) | catalogued as COSV99555174; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640551 C>T | 3'Flank (SNP) | VAF 27/135 reads (20%) | catalogued as rs140602857, COSV51705375; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5241C>T | Intron (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100446997; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790976 C>G | 5'Flank (SNP) | VAF 87/193 reads (45%) | called by muse, mutect2, varscan2
- RPA4 | c.*2G>A | 3'UTR (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100232645; called by muse, mutect2, varscan2
